Somatic mutation profile of tumor specimen ccaab7e8-e841-4397-80aa-370b58 (aliquot ccaab7e8-e841-4397-80aa-370b58_D6_1) from CPTAC case 05CO055, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC.
Specimen ccaab7e8-e841-4397-80aa-370b58: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3abe2efc-2852-4cfc-9541-05aafb67bd31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 16c0626f-d1a6-4e24-b371-552643 (Blood Derived Normal), aliquot 16c0626f-d1a6-4e24-b371-552643_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1d0e854-3c69-41b2-8fba-a40427478bff

The open-access MAF lists 109 somatic variants for this specimen: 68 protein-altering or splice-affecting, 30 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 30, Intron 6, Nonsense Mutation 4, Frame Shift Del 2, 3'Flank 2, 3'UTR 2, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.993+1G>A p.X331_splice | Splice Site (SNP) | VAF 69/163 reads (42%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADCY8 | c.1211G>T p.R404L | Missense Mutation (SNP) | VAF 64/297 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV53907039; called by muse, mutect2, varscan2
- APC | c.4037C>G p.S1346* | Nonsense Mutation (SNP) | VAF 131/471 reads (28%) | catalogued as COSV57325995, COSV57328373, COSV57364395; called by muse, varscan2
- APC | c.4059del p.E1353Dfs*62 | Frame Shift Del (DEL) | VAF 118/438 reads (27%) | catalogued as COSV57402047; called by pindel, varscan2
- ARID1A | c.4948C>T p.Q1650* | Nonsense Mutation (SNP) | VAF 60/101 reads (59%) | catalogued as COSV61375520, COSV61383665; called by muse, mutect2, varscan2
- CAPN6 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 170/299 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.43); catalogued as rs1288424206; called by muse, mutect2, varscan2
- CEP120 | c.1858C>G p.Q620E | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV60265469; called by muse, mutect2, varscan2
- CNTN6 | c.220A>C p.S74R | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as COSV63160327, COSV63180477; called by muse, mutect2, varscan2
- CSRP2 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.462); catalogued as rs762670612, COSV60702849, COSV60703473; called by muse, mutect2, varscan2
- DNHD1 | c.1988G>A p.R663H | Missense Mutation (SNP) | VAF 137/515 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs781073836, COSV54437199; called by muse, mutect2, varscan2
- DOCK3 | c.4825C>T p.R1609W | Missense Mutation (SNP) | VAF 147/265 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372827222; called by muse, mutect2, varscan2
- DST | c.10279G>A p.A3427T | Missense Mutation (SNP) | VAF 62/105 reads (59%) | SIFT tolerated (0.39); PolyPhen benign (0.027); catalogued as rs1241510268; called by muse, mutect2, varscan2
- MYH13 | c.3146G>A p.R1049Q | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs545467762, COSV52845504, COSV99352986; called by muse, mutect2, varscan2
- NLRP1 | c.1606C>T p.R536W | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs201070268; called by muse, mutect2, varscan2
- OR5D18 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 96/318 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as rs768748128, COSV100450684, COSV61736976; called by muse, mutect2, varscan2
- OR8U1 | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV100164196; called by muse, varscan2
- PROX1 | c.1882C>T p.R628C | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54783648; called by muse, mutect2, varscan2
- PTGIR | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 83/319 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs764800481, COSV52192156; called by muse, mutect2, varscan2
- RASL12 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs372723731; called by muse, mutect2, varscan2
- RASSF8 | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs776942032; called by muse, mutect2, varscan2
- SF3B3 | c.2240C>T p.S747L | Missense Mutation (SNP) | VAF 66/298 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs765817626; called by muse, mutect2, varscan2
- SHC3 | c.989C>T p.T330M | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs541388113, COSV65437002; called by muse, mutect2, varscan2
- SLC6A4 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 60/204 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as rs201425535; called by muse, mutect2, varscan2
- SMAD4 | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 59/137 reads (43%) | catalogued as COSV61686624; called by muse, mutect2, varscan2
- SMPD4 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 69/184 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs781097935; called by muse, mutect2, varscan2
- SYCP2 | c.2272C>A p.P758T | Missense Mutation (SNP) | VAF 107/174 reads (61%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.478); catalogued as COSV62773077; called by muse, mutect2, varscan2
- TAF9B | c.526A>G p.M176V | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781802816; called by muse, mutect2
- TBX22 | c.1141T>G p.W381G | Missense Mutation (SNP) | VAF 289/704 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as COSV64785694; called by muse, mutect2, varscan2
- TOR4A | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 182/522 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.166); catalogued as rs1037531878; called by muse, mutect2, varscan2
- TRIM37 | c.616G>A p.G206S | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.082); catalogued as COSV51881288; called by muse, mutect2, varscan2
- TRPS1 | c.383C>T p.P128L (on ENST00000220888 / NM_001330599.2; = p.P141L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 139/590 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs201699015; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSHZ2 | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 35/354 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs772340421; called by muse, mutect2, varscan2
- UXS1 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs762838871, COSV51680401; called by muse, mutect2, varscan2
- XRN1 | c.2942C>T p.S981F | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.401); catalogued as rs1402655475, COSV53819182; called by muse, mutect2, varscan2
- ZDHHC4 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 169/531 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781761812, COSV60105939; called by muse, mutect2, varscan2
- ZNF25 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.559); catalogued as COSV56923046; called by muse, mutect2, varscan2
- ZNF341 | c.2164C>T p.R722C (on ENST00000375200 / NM_001282935.1; = p.R715C on NM_032819.4) | Missense Mutation (SNP) | VAF 113/726 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs368945563, COSV100677567; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF469 | c.10724G>A p.R3575Q (on ENST00000437464; = p.R3603Q on NM_001367624.2) | Missense Mutation (SNP) | VAF 163/323 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0.03); catalogued as rs537930010; called by muse, mutect2, varscan2
- ZNF716 | c.118T>A p.L40I | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101348598; called by muse, mutect2, varscan2
- ARAP2 | c.2108G>T p.C703F | Missense Mutation (SNP) | VAF 120/450 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP5 | c.2200G>A p.A734T | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ASXL3 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP11C | c.3223C>T p.L1075F | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CDH11 | c.38G>C p.C13S | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CFAP91 | c.1877G>A p.R626Q | Missense Mutation (SNP) | VAF 50/82 reads (61%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFTR | c.2118C>G p.N706K | Missense Mutation (SNP) | VAF 105/272 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAH10 | c.485T>G p.F162C (on ENST00000409039; = p.F101C on NM_207437.3) | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- EN2 | c.140C>A p.A47D | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); called by muse, mutect2
- FAT3 | c.1844T>C p.I615T | Missense Mutation (SNP) | VAF 75/186 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- FLG2 | c.2254T>C p.S752P | Missense Mutation (SNP) | VAF 312/1438 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.038); called by mutect2, varscan2
- GRM3 | c.584T>G p.F195C | Missense Mutation (SNP) | VAF 111/419 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IGLV4-3 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 212/718 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- INTS5 | c.1933C>G p.L645V | Missense Mutation (SNP) | VAF 42/347 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- MAP3K8 | c.338T>C p.V113A | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- MEMO1 | c.705C>G p.Y235* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- METTL11B | c.335C>G p.P112R | Missense Mutation (SNP) | VAF 202/387 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2
- NEK11 | c.1106A>G p.E369G | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.215); called by muse, mutect2
- PCYOX1 | c.968A>C p.N323T | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- PPP1R42 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPN12 | c.360G>T p.M120I | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC26A2 | c.1786A>C p.K596Q | Missense Mutation (SNP) | VAF 113/410 reads (28%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SPATA31A3 | c.1959C>A p.S653R | Missense Mutation (SNP) | VAF 133/602 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- STAT3 | c.752G>A p.C251Y | Missense Mutation (SNP) | VAF 83/244 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TENM3 | c.1811A>G p.Y604C | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- TRAJ23 | c.6del p.Y3Ifs*17 | Frame Shift Del (DEL) | VAF 86/302 reads (28%) | called by mutect2, pindel, varscan2
- VPS13D | c.5558A>C p.H1853P | Missense Mutation (SNP) | VAF 110/188 reads (59%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- WDR36 | c.2341C>T p.P781S | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF469 | c.8801C>G p.A2934G (on ENST00000437464; = p.A2962G on NM_001367624.2) | Missense Mutation (SNP) | VAF 122/483 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- ADGRE2 | c.1932G>A p.K644= | Silent (SNP) | VAF 60/261 reads (23%) | called by muse, mutect2, varscan2
- ATP10A | c.1557G>A p.K519= | Silent (SNP) | VAF 34/716 reads (5%) | catalogued as rs758204594; called by muse, mutect2
- ATP13A1 | c.1239C>T p.Y413= | Silent (SNP) | VAF 155/603 reads (26%) | catalogued as rs527630015, COSV52291320; called by muse, mutect2, varscan2
- C4orf50 | c.426C>T p.D142= (on ENST00000324058; = p.D1374= on NM_001364689.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 71/296 reads (24%) | catalogued as rs115562230; called by muse, mutect2, varscan2
- C5orf47 | c.300C>T p.S100= | Silent (SNP) | VAF 10/149 reads (7%) | catalogued as rs1480927496, COSV60864626; called by muse, mutect2
- COL6A3 | c.2589C>T p.I863= | Silent (SNP) | VAF 95/308 reads (31%) | catalogued as rs376409920; called by muse, mutect2, varscan2
- DNM3 | c.1653T>G p.L551= (on ENST00000355305 / NM_001350206.2; = p.L541= on NM_015569.5) | Silent (SNP) | VAF 57/253 reads (23%) | called by muse, mutect2, varscan2
- DSE | c.435T>A p.P145= | Silent (SNP) | VAF 59/243 reads (24%) | called by muse, mutect2, varscan2
- ELMO1 | c.1059G>A p.T353= | Silent (SNP) | VAF 94/373 reads (25%) | catalogued as rs757164649, COSV60332658; called by muse, mutect2, varscan2
- EPHA7 | c.330C>T p.N110= | Silent (SNP) | VAF 87/303 reads (29%) | called by muse, mutect2, varscan2
- ESM1 | c.444T>C p.S148= | Silent (SNP) | VAF 42/162 reads (26%) | called by muse, mutect2, varscan2
- GLE1 | c.165C>T p.H55= | Silent (SNP) | VAF 198/629 reads (31%) | catalogued as rs768406713, COSV59411003; called by muse, mutect2, varscan2
- GRM2 | c.2607G>A p.T869= | Silent (SNP) | VAF 79/301 reads (26%) | catalogued as rs369553502; called by muse, mutect2, varscan2
- HP1BP3 | c.78C>T p.H26= | Silent (SNP) | VAF 111/190 reads (58%) | catalogued as rs746576147, COSV56562267; called by muse, mutect2, varscan2
- KCNQ3 | c.2208C>G p.S736= | Silent (SNP) | VAF 167/793 reads (21%) | called by muse, mutect2, varscan2
- MSS51 | c.1263G>A p.Q421= | Silent (SNP) | VAF 50/212 reads (24%) | called by muse, mutect2, varscan2
- MYO16 | c.4470G>A p.P1490= | Silent (SNP) | VAF 138/264 reads (52%) | catalogued as COSV100696345; called by muse, mutect2, varscan2
- NLRC5 | c.2739C>T p.A913= | Silent (SNP) | VAF 265/653 reads (41%) | catalogued as rs533171843; called by muse, mutect2, varscan2
- OPRK1 | c.306T>C p.A102= | Silent (SNP) | VAF 116/263 reads (44%) | called by muse, mutect2, varscan2
- PABPC1L | c.1614G>A p.A538= | Silent (SNP) | VAF 24/440 reads (5%) | catalogued as rs755759350; called by muse, mutect2
- PCDHB12 | c.1023C>T p.N341= | Silent (SNP) | VAF 16/448 reads (4%) | catalogued as rs782673787, COSV53393314; called by muse, mutect2
- PLEKHF1 | c.435C>T p.H145= | Silent (SNP) | VAF 124/421 reads (29%) | called by muse, mutect2, varscan2
- PLPPR3 | c.729C>T p.I243= (on ENST00000520876 / NM_001270366.2; = p.I271= on NM_024888.2) | Silent (SNP) | VAF 135/523 reads (26%) | catalogued as rs758044499; called by muse, mutect2, varscan2
- PTPN14 | c.2400C>T p.N800= | Silent (SNP) | VAF 116/495 reads (23%) | catalogued as rs752416621; called by muse, mutect2, varscan2
- SYNE1 | c.4929G>A p.A1643= (on ENST00000367255 / NM_182961.4; = p.A1650= on NM_033071.3) | Silent (SNP) | VAF 200/662 reads (30%) | catalogued as rs779511296; called by muse, mutect2, varscan2
- TENM3 | c.7770G>A p.T2590= | Silent (SNP) | VAF 89/348 reads (26%) | catalogued as rs374291348; called by muse, mutect2, varscan2
- TET2 | c.5772A>G p.K1924= | Silent (SNP) | VAF 111/332 reads (33%) | called by muse, mutect2, varscan2
- TEX37 | c.129G>A p.K43= | Silent (SNP) | VAF 41/163 reads (25%) | catalogued as rs1165510031, COSV100304615, COSV57555813; called by muse, mutect2, varscan2
- TUBGCP3 | c.528G>A p.A176= | Silent (SNP) | VAF 257/554 reads (46%) | catalogued as rs758814255; called by muse, mutect2, varscan2
- ZNF629 | c.1725A>G p.G575= | Silent (SNP) | VAF 98/430 reads (23%) | catalogued as rs1340764348; called by muse, mutect2, varscan2
- FCGR2B | c.818-38A>G | Intron (SNP) | VAF 29/131 reads (22%) | called by muse, mutect2, varscan2
- GNA12 | c.310-19738G>T | Intron (SNP) | VAF 140/367 reads (38%) | called by muse, mutect2, varscan2
- LRP12 | chr8:104484430 G>A | 3'Flank (SNP) | VAF 35/161 reads (22%) | catalogued as rs1462510220; called by muse, mutect2, varscan2
- MARK3 | c.1872-43dup | Intron (INS) | VAF 34/133 reads (26%) | called by mutect2, pindel, varscan2
- MUC19 | chr12:40546437 A>C | 3'Flank (SNP) | VAF 25/393 reads (6%) | called by muse, mutect2
- NOC2L | c.179+69C>T | Intron (SNP) | VAF 108/358 reads (30%) | called by muse, mutect2, varscan2
- OBP2A | c.*55G>A | 3'UTR (SNP) | VAF 47/233 reads (20%) | catalogued as rs200533613; called by muse, mutect2, varscan2
- PCNT | c.*47G>C | 3'UTR (SNP) | VAF 23/81 reads (28%) | catalogued as COSV64032777; called by muse, mutect2, varscan2
- THAP4 | c.1614+12C>G | Intron (SNP) | VAF 109/429 reads (25%) | called by muse, mutect2, varscan2
- TP73-AS1 | n.1282C>T | RNA (SNP) | VAF 360/591 reads (61%) | called by muse, mutect2, varscan2
- YAF2 | c.152+1893G>A | Intron (SNP) | VAF 60/160 reads (38%) | called by muse, mutect2, varscan2
